Somatic mutation profile of tumor specimen TCGA-EL-A3TB-01A (aliquot TCGA-EL-A3TB-01A-11D-A22D-08) from TCGA case TCGA-EL-A3TB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.1 years (17,195 days).
Specimen TCGA-EL-A3TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ba76c60-3c85-43cc-81c9-4877ef4fceb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3TB-11A (Solid Tissue Normal), aliquot TCGA-EL-A3TB-11A-11D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4546e63-831b-418a-a950-d45ec9e424eb

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267605206, COSV59087112; called by muse, mutect2, varscan2
- EPHA6 | c.2173A>T p.I725F (on ENST00000389672 / NM_001080448.3; = p.I117F on NM_173655.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67583109; called by muse, mutect2, varscan2
- GPN1 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV53116191; called by muse, mutect2
- GRM4 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65216087; called by muse, mutect2, varscan2
- PRKAR2A | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769798310, COSV55553115; called by muse, mutect2, varscan2
- PRSS57 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV51261786; called by muse, mutect2, varscan2
- RBM15 | c.636C>G p.S212R | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV63923912; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 48/129 reads (37%) | PolyPhen probably damaging (0.927); catalogued as COSV52536061; called by muse, mutect2, varscan2
- TCP11L1 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57516532; called by muse, mutect2, varscan2
- TTN | c.97262T>C p.M32421T (on ENST00000591111; = p.M24997T on NM_003319.4) | Missense Mutation (SNP) | VAF 46/121 reads (38%) | PolyPhen probably damaging (0.992); catalogued as COSV59965268; called by muse, mutect2, varscan2
- VCAM1 | c.1645C>A p.Q549K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV54117749; called by muse, mutect2, varscan2
- POLE2 | c.660_665del p.E220_C222delinsD | In Frame Del (DEL) | VAF 25/120 reads (21%) | called by mutect2, pindel, varscan2
- ZNF592 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.035); called by mutect2, varscan2
- F2RL1 | c.549C>T p.H183= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV56996237; called by muse, mutect2
- FEZ1 | c.66C>T p.D22= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV54030218; called by muse, mutect2, varscan2
- MUC17 | c.10470C>T p.T3490= | Silent (SNP) | VAF 165/397 reads (42%) | catalogued as COSV60296142; called by muse, mutect2, varscan2
- WWC1 | c.2991G>A p.A997= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs372157598; called by muse, mutect2, varscan2
